Somatic mutation profile of tumor specimen TCGA-V1-A8WS-01A (aliquot TCGA-V1-A8WS-01A-11D-A377-08) from TCGA case TCGA-V1-A8WS, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8WS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ed6d41e-b13d-45c7-a96c-c6bbfa4f3141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8WS-10A (Blood Derived Normal), aliquot TCGA-V1-A8WS-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11a1cce-7d6c-494f-aa06-46102ce0fb49

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF7IP2 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100202657; called by muse, mutect2, varscan2
- CCDC171 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99901164; called by muse, mutect2, varscan2
- CFAP206 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1469981004, COSV99739754; called by muse, mutect2
- CHRNA10 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285565282, COSV99167194; called by muse, mutect2, varscan2
- FAM47B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370213556, COSV61453664; called by muse, mutect2, varscan2
- FAM83D | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99465302; called by muse, mutect2, varscan2
- GRIA4 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99232567; called by muse, mutect2, varscan2
- HIVEP3 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746325865, COSV56008983; called by muse, mutect2, varscan2
- OPRL1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100402154; called by muse, mutect2, varscan2
- PCDHB10 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs782534809, COSV99504555; called by muse, mutect2, varscan2
- PON2 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778890057, COSV99749795; called by muse, mutect2, varscan2
- RALGPS1 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99401926; called by muse, mutect2, varscan2
- RASEF | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV64586862, COSV64587248; called by muse, mutect2, varscan2
- RPL11 | c.211T>C p.C71R (on ENST00000374550 / NM_001199802.1; = p.C72R on NM_000975.5) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV100999671; called by muse, mutect2, varscan2
- SLC38A7 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99543830; called by muse, mutect2, varscan2
- SPTA1 | c.812G>T p.R271M | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935151, COSV63756531; called by muse, mutect2
- TMIGD2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs538543729, COSV100010357; called by muse, mutect2, varscan2
- WDR33 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100460295; called by muse, mutect2
- ZNF468 | c.1562A>C p.K521T | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99700643; called by muse, mutect2, varscan2
- ZNF804B | c.2603G>A p.S868N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100304533, COSV60835168; called by muse, mutect2, varscan2
- C4orf17 | c.33G>A p.Q11= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100430990; called by muse, mutect2, varscan2
- CXorf38 | c.30C>T p.L10= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs1253149651, COSV100010447; called by muse, mutect2, varscan2
- GRIA1 | c.159G>A p.P53= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs755342972, COSV53591151; called by muse, mutect2
- MAP3K14 | c.2028G>A p.P676= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1023427255, COSV100766510; called by muse, mutect2
- PROP1 | c.423C>T p.A141= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs200977367, COSV57645052; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- SLC12A5 | c.1119C>A p.A373= (on ENST00000454036 / NM_001134771.2; = p.A350= on NM_020708.5) | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1568861790, COSV99716350; called by muse, mutect2, varscan2
